Somatic mutation profile of tumor specimen 0DU3LI from CCDI case PBCKKY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 13.8 years (5,047 days).
Specimen 0DU3LI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8897711c-4ae6-4eef-aef2-37ee40a0bb35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU3MO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12ab8ff8-8d5d-45a0-b670-4150e7629574

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 1, Silent 1, Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LIPE | c.2984C>T p.P995L | Missense Mutation (SNP) | VAF 117/617 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1008817231; called by muse, mutect2, varscan2
- CYP2C19 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 232/1342 reads (17%) | called by muse, mutect2, varscan2
- EDRF1 | c.3027G>A p.V1009= (on ENST00000356792 / NM_001202438.2; = p.V975= on NM_015608.2) | Silent (SNP) | VAF 312/1609 reads (19%) | called by muse, mutect2, varscan2
- FOXS1 | c.*16G>C | 3'UTR (SNP) | VAF 215/1117 reads (19%) | catalogued as rs989812947, COSV99639745; called by muse, mutect2, varscan2
